TARGET case TARGET-15-SJMPAL040030 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3219ef77-f370-48b5-bf41-2f3e36543330

Demographics
Sex at birth: female; Age at index: 13 years; Vital status: Dead; Days to death: 66 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 13.5 years (4,931 days); Year of diagnosis: 2011; Days to last follow up: 66 days.

Follow-up (1 entry)
- Days to follow up: 66 days; Event-free: no event (relapse, second malignancy or death) recorded through day 66; Year of follow up: 2011.

Biospecimens (6 samples)
- Samples TARGET-15-SJMPAL040030-09A, TARGET-15-SJMPAL040030-09A.1, TARGET-15-SJMPAL040030-09A.2, TARGET-15-SJMPAL040030-09A.3, TARGET-15-SJMPAL040030-09A.4 (5 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMPAL040030-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 66
- Protocol: DCOG
- Karyotype: 46,XX
- WHO ALAL Classification: B/M
- WHO Dx: B/M
